CGCI case HTMCP-02-25-01235 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Paragangliomas and Glomus Tumors; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74934f2b-42e5-44fd-8fe8-6a917b24c5ec

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead; Cause of death: Cancer Related.

Diagnoses (2)
1. Pheochromocytoma, malignant (the primary disease): ICD-O-3 morphology code: 8700/3; Tissue or organ of origin: Lung, NOS; Classification of tumor: primary; Year of diagnosis: 2004; Prior malignancy: yes; Prior treatment: No; Days to last follow up: 0 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.
2. Neoplasm, NOS: Tissue or organ of origin: Other ill-defined sites; Classification of tumor: Prior primary.

Follow-up (2 entries)
- Days to follow up: 0 days; Karnofsky performance status: 0.
- Disease response: With Tumor.

Molecular and laboratory tests
- Test (IHC): Negative; Specialized molecular test: P40.

Other clinical attributes
- Day 0: Haart treatment indicator: Yes; HIV viral load: 0.
- Day 0: Risk factors: Pneumocystis Pneumonia.
- Day 0: Comorbidities: Pneumocystis Pneumonia.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-02-25-01235-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-25-01235-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-25-01235-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Lung metastatic pheochromocytoma; Tumor status: With tumor; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: No; Tobacco smoking history indicator: 1; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1981; HIV rna load at diagnosis: 0; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact; History relevant infectious diagnosis: PCP pneumonia.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-25-01235-01B-01D-12322:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-25-01235-11A-01D-11827:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-25-01235-01B-01R-12322:
- % tumour top: 70
- % tumour bottom: 70
